Somatic mutation profile of tumor specimen 0DMN27 from CCDI case PBCASY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Choroid plexus papilloma, NOS; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 5.7 years (2,078 days).
Specimen 0DMN27: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d8bda68-f207-4168-8142-f50621fe5e16.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMN1E (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc617411-fa1e-40bf-abef-bfaad4632592

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CKM | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 22/582 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as rs1313579937, COSV99488903; called by muse, mutect2
- FOXD1 | c.974C>A p.T325N | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.146); called by muse, varscan2
- RPL4 | c.-12C>T | 5'UTR (SNP) | VAF 137/508 reads (27%) | catalogued as rs745911727; called by muse, mutect2, varscan2
